Gene-level copy-number profile of tumor specimen ALCH-B1SB-TTP1-A from ALCHEMIST case ALCH-B1SB, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.4 years (23,885 days).
Specimen ALCH-B1SB-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 21fa754e-5afb-4b39-bf8d-6ac663a0a6ea.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1SB-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,246 have no estimate.
https://portal.gdc.cancer.gov/files/580e9f6f-ba6e-4a03-bef3-f261dac49559

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 23; copy number 1: 3,453; copy number 2: 49,727; copy number 3: 4,870; copy number 4: 303; copy number 6: 1.

Homozygous deletions (total copy number 0; autosomes only): 23 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:10,330,229–10,330,285, 1 gene (within-gene range 0–2): MIR378B.
- chr3:52,048,919–52,056,571, 1 gene: DUSP7.
- chr4:573,880–576,295, 1 gene: TMEM271.
- chr8:143,945,191–143,945,279, 1 gene (within-gene range 0–2): MIR661.
- chr9:127,716,079–127,735,313, 2 genes (within-gene range 0–2): TTC16, TOR2A.
- chr9:137,007,234–137,028,922, 1 gene (within-gene range 0–2): ABCA2.
- chr11:118,893,875–118,925,608, 2 genes (within-gene range 0–2): BCL9L, MIR4492.
- chr12:132,144,457–132,152,473, 1 gene: NOC4L.
- chr14:103,100,144–103,110,559, 1 gene: EXOC3L4.
- chr15:41,503,637–41,513,887, 1 gene: LTK.
- chr15:85,958,717–85,958,971, 1 gene: AC104229.1.
- chr16:67,644,988–67,660,815, 2 genes: CARMIL2, ACD.
- chr16:88,696,499–88,706,408, 2 genes: RNF166, AC138028.3.
- chr17:50,944,104–50,948,750, 1 gene (within-gene range 0–2): AC005920.3.
- chr19:50,505,998–50,514,690, 2 genes: JOSD2, ASPDH.
- chr22:20,129,456–20,148,007, 1 gene: ZDHHC8.
- chr22:46,006,616–46,015,498, 2 genes: BX537318.2, BX537318.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:132,462,242–132,462,856, 1 gene, copy number 6: AC079031.2.

Autosomal genes at a single copy (total copy number 1): 3,448. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
